Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8256, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8256-01A (Primary Tumor).

[page 1 of 3]
Patient

Note: All result statuses are Final unless otherwise noted.

Tests: (1) Path Report

Prostate

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 3+4=7.
- Both sides of prostate involved by tumor.
- Tumor involves 10% of sampled prostate tissue.
- No extraprostatic extension identified.
- Seminal vesicles and vas deferentia not involved by tumor.
- No lymphovascular or perineural invasion identified.
- MARGINS: NEGATIVE (URETHRAL, BLADDER NECK, AND RADIAL).
- REGIONAL LYMPH NODES: NOT IDENTIFIED.
- HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS ALSO IDENTIFIED.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Histologic type and grade: Prostatic adenocarcinoma, Gleason grade 3+4=7.

Primary tumor (pT): pT2c.

Regional lymph nodes (pN): pNX.

Distant metastasis (pM): pMX.

Margin status (R): R0.

Pathology stage: IIB.

Lymphovascular invasion: Not identified.

Perineural invasion: Not identified.

Prostate Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, and CAP protocol,

| Procedure: | Radical prostatectomy.

Specimen type: | Prostate.

Prostate size/weight: | 2.6 x 4.1 x 3.4 cm, 34 g.

TUMOR FEATURES:

Tumor site: | Right and left side of prostate.

Tumor size: | Cannot be accurately determined.

Tumor quantification: | 10% of sampled tissue.

Histologic type: | Prostatic adenocarcinoma.

Histologic grade: | 3+4=7.

Primary pattern: | 3.

Secondary pattern: | 4.

Tertiary pattern: |

Total Gleason score: | 7.

Lymphovascular invasion: | Not identified.

[page 2 of 3]
Perineural invasion:|Not identified.
Extraprostatic extension:|Not identified.
Seminal vesicle invasion:|Not identified.
Treatment effect:|Not identified.
|
LYMPH NODES:|No lymph nodes identified.
|
MARGIN EVALUATION:|
Distance to closest margin:|0.1cm.
Other margins:|Negative.
|
PATHOLOGIC TUMOR STAGING DESCRIPTORS:|
Primary tumor:|p2c.
Regional lymph nodes:|pNX.
Distant metastasis:|pMX.
Margin status:|R0.
Pathologic stage:|IIB.
|
Additional findings:|High grade prostatic intraepithelial neoplasia.
|
Comment:|N/A.|

Source of Specimen:
Prostate

Clinical History/Operative Dx:
Prostate cancer

Gross Description:

Received is a single specimen designated as prostate. Initially received in the fresh state for possible tumor bank studies is a radical prostatectomy and two additional fragments of vas deferens. The prostate is 34 grams and 2.6 cm apex to base, 4.1 cm across and 3.4 cm posterior-anterior. The prostate margins are shaggy, congested, deep red and are now differentially inked: posterior - black, right anterior-lateral - blue, left anterior-lateral - orange. The right and left vas deferens extend out to 0.7 x 0.5 cm and 0.6 x 0.5 cm, respectively. The bilateral seminal vesicles extend 2.2 x 1.8 cm. Sectioning through the seminal vesicles demonstrates a rubbery, light pink and tan honeycomb cut surfaces without gross tumor involvement. The vas margins are grossly negative. The separate vas deferens segments within the container are 3.0 x 0.5 cm (now marked yellow) and 1.7 x 0.5 cm each. The prostate is serially sectioned apex to base, initially revealing a poorly defined, glistening, yellow-orange area of change dominating the right body toward the apex, upwards of 0.7 x 0.5 x 0.5 cm. A representative portion of this area suspicious for malignancy is submitted for tumor bank studies along with representation of the seminal vesicles. This area is noted within 0.3 cm of the anterior-lateral apical margin. The cut sections of the prostate demonstrate a rubbery to indurated, multinodular cut surface with additional suspicious induration along the right to mid posterior periphery through the apical half of the specimen. The origin of the seminal vesicles appears grossly free of tumor involvement. Representative sections are submitted to include representation of right and left body of prostate and the entire radial surgical margin. Following initial microscopic evaluation, the remainder of the right and left body of prostate is submitted for microscopic evaluation, in A21-A27, excluding the remnant of the bilateral seminal vesicles and vas deferens.

[page 3 of 3]
[REDACTED]

Cassette summary: A1) separate vas deferens segments, represented, A2) right and left vas deferens margins, A3) right and left seminal vesicles, represented, A4-A5) right and left apex, respectively, sectioned and submitted, A6-A7) right and left base, respectively, sectioned and submitted, A8-A10) right body of prostate, anterior-lateral, apex to base, A11-A13) right body of prostate, posterior-lateral, apex towards base, A14-A16) left anterior-lateral prostate, apex towards base, A17-A20) left posterior-lateral prostate, apex towards base, A21-A23) likely left residual body of prostate submitted, A24-A27) remainder of prostate, including fragments marked blue (right).

Microscopic Description:
Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Note: An exclamation mark (!) indicates a result that was not dispersed into the flowsheet.
Document Creation Date: [REDACTED]

(1) Order result status: Final [REDACTED]
Collection or observation date-time: [REDACTED]
Requested date-time: [REDACTED]
Receipt date-time: [REDACTED]
Reported date-time: [REDACTED]
Referring Physician: [REDACTED]
Ordering Physician: [REDACTED]
Specimen Source: Biopsy
Source: [REDACTED]
Filler Order Number: [REDACTED]
Lab site: [REDACTED]
Producer ID [REDACTED]

External Attachment:
Type: Image
Comment: External Document - Imported By: [REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 9b315ba9-4f27-4a9b-aab2-2bd577bf166d (TCGA-HC-8256.2EC7732C-F24C-41EB-BA84-39BFC1C0C5B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).